Somatic mutation profile of tumor specimen ER-B0C3-TTM1-A (aliquot ER-B0C3-TTM1-A-1-0-D-A670-35) from EXCEPTIONAL_RESPONDERS case ER-B0C3, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 61.1 years (22,315 days).
Specimen ER-B0C3-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c71fc334-cd2f-44c7-9dc4-2817611e1b05.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-B0C3-NB1-A (Blood Derived Normal), aliquot ER-B0C3-NB1-A-1-0-D-A75L-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1e338f6-406b-44f3-b274-4d1b31379e70

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3809G>A p.G1270D | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59259050; called by muse, mutect2, varscan2
- CYP2C8 | c.1212_1221del p.N405Tfs*6 | Frame Shift Del (DEL) | VAF 32/178 reads (18%) | called by mutect2, pindel, varscan2
